CCDI case PBBNLI — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/fb5d8357-096f-4285-aa33-d0d60d32738a

Demographics
Sex at birth: female; Race: asian.

Diagnoses (1)
1. Spindle cell carcinoma, NOS: ICD-O-3 morphology code: 8032/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 12.4 years (4,540 days).

Biospecimens (3 samples)
- Sample 0DXV66: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DXV6C: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DXV6I: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
